Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A1KS, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A1KS-01A (Primary Tumor).

[page 1 of 8]
Clinical Diagnosis & History:

Invasive lobular (questionable duct), carcinoma left breast LOQ for left wide excision with needle localization, SLNB.

Specimens Submitted:

- 1: SP: Sentinel node #1 level one left axilla
- 2: SP: Sentinel node #2 level one left axilla
- 3: SP: Non-sentinel tissue left axilla
- 4: SP: Sentinel node #3 level one left axilla
- 5: SP: Breast, left, 4:00, excision of tumor site
- 6: SP: Breast, left, superior margin
- 7: SP: Breast, left, medial margin
- 8: SP: Breast, left, inferior margin
- 9: SP: Breast, left, lateral margin
- 10: SP: Breast, left, posterior margin

DIAGNOSIS:

1. SP: Sentinel node #1 level one left axilla:
Sentinel Lymph Node Status:
No carcinoma present
Number of Sentinel Lymph Nodes Examined: 1
Level of Detection:
Initial H&E stained section
Deeper H&E stained sections and cytokeratin AE1:AE3 stains
Extracapsular Extension:
Not applicable

2. SP: Sentinel node #2 level one left axilla:
Sentinel Lymph Node Status:
No carcinoma present
Number of Sentinel Lymph Nodes Examined: 1
Level of Detection:
Initial H&E stained section
Deeper H&E stained sections and cytokeratin AE1:AE3 stains
Extracapsular Extension:
Not applicable

** Continued on next page **

ICD-O-3
Carcinoma, infiltrating lobular 8520/3
Site: breast, NOS C50.9 2/16/11
fw

[page 2 of 8]
3. SP: Non-sentinel tissue left axilla:
Two benign lymph nodes (0/2)

4. SP: Sentinel node #3 level one left axilla:
Sentinel Lymph Node Status:
No carcinoma present
Number of Sentinel Lymph Nodes Examined: 1
Level of Detection:
Initial H&E stained section
Deeper H&E stained sections and cytokeratin AE1:AE3 stains
Extracapsular Extension:
Not applicable

5. SP: Breast, left, 4:00, excision of tumor site:
Invasive Carcinoma:
Invasive mammary carcinoma (see comments)
Histologic Grade:
III/III: Minimal or no tubule formation (< 10% of tumor)
Nuclear Grade:
III/III (marked variation in size and shape)
Tumor Size:
Gross measurement 26mm
Lobular Neoplasia:
Lobular carcinoma in situ (LCIS), classical type
focal
Calcification:
Not Identified
Lymphovascular Invasion:
Not present
Surgical Margins:
For Final margin status see separately submitted margins
Benign Breast Tissue:
Biopsy site change=
Estrogen Receptor (6F11, V)
Positive nuclear staining in 99% of tumor cells
Strong intensity
Progesterone Receptor (1E2; Ventana):
Positive nuclear staining in 90% of tumor cells
Strong intensity
Moderate intensity
HER2 (4B5,
equivocal (2+). FISH will be performed.
Membranous Staining (for Her2 positive and equivocal cases only):
15% of invasive cells exhibit complete membranous staining
Uniformity of staining is absent
Homogenous, dark circumferential pattern is absent
Comment: This high grade invasive carcinoma has a solid growth pattern.
There is focal associated LCIS. Based on the cytomorphology and the fact
that it is E-Cadherin negative, most likely this is an invasive lobular ca

** Continued on next page **

[page 3 of 8]
with pleomorphic features.

Page 3 of 7

6. SP: Breast, left, superior margin:
Benign breast parenchyma
7. SP: Breast, left, medial margin:
Benign breast parenchyma and skeletal muscle
8. SP: Breast, left, inferior margin:
Benign breast parenchyma
9. SP: Breast, left, lateral margin:
Benign breast parenchyma
10. SP: Breast, left, posterior margin:
Benign breast parenchyma and skeletal muscle

Comment:

Controls are satisfactory. Ventana's PATHWAY anti-HER-2/neu is an FDA-approved rabbit monoclonal primary antibody (clone 4B5) directed against the internal domain of the c-erbB-2 oncoprotein (HER2) for immunohistochemical detection of HER2 protein overexpression in breast cancer tissue routinely processed for histologic evaluation. Results are reported in accordance with the ASCO/CAP guideline recommendations for HER2 testing in breast cancer (J Clin Oncol 2007; 25(1):118-145). ER and PR are also rabbit monoclonal antibodies which are FDA approved. Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received in formalin, labeled "Sentinel node #1 level 1 left axilla" and consists of a gray-tan lymph node measuring 2.2 cm in greatest dimension. The lymph node is bisected and submitted entirely.

** Continued on next page **

[page 4 of 8]
Summary of sections:
BLN - bisected lymph node

2) The specimen is received in formalin, labeled "Sentinel node #2 level 1 left axilla" and consists of a pink-tan lymph node measuring 1.1 cm in greatest dimension, which is bisected and submitted entirely.

Summary of sections:
U undesignated

3) The specimen is received in formalin, labeled "Non-sentinel tissue left axilla" and consists of a piece of fatty tissue measuring 4.5 x 4.5 x 0.5 cm in greatest dimension. A few pink-tan lymphoid nodules are identified ranging from 0.1 to 0.7 cm in greatest dimension, which are entirely submitted.

Summary of sections:
U - undesignated

4) The specimen is received in formalin, labeled "Sentinel node #3 level 1 left axilla" and consists of a pink-tan lymph node measuring 0.5 cm in greatest dimension, which is submitted whole.

Summary of sections:
U undesignated

5) The specimen is received fresh labeled "Excision of tumor site at 4 o'clock left breast." It consists of an unoriented segment of yellow-tan fatty breast tissue measuring 8.5 x 6.5 x 3.4 cm. The specimen is received on a cardboard grid. There is an accompanying specimen radiograph which demonstrates a solid tumor mass containing a previous biopsy clip. The outer surface of the specimen is inked black. In sections reveal a 2.6 x 2.4 x 2.2 cm well circumscribed, stony hard, white-tan tumor with a central previous biopsy site measuring 0.8 x 0.7 x 0.6 cm. A stereotactic biopsy clip is identified within the biopsy site. The tumor abuts the black inked tissue edge. The remainder of the breast tissue is predominantly yellow tan fatty and lobulated with focal white-tan fibrous areas. A sample of the tumor is given to TPS. The remainder of the tumor is blocked out, sequentially sectioned, and submitted entirely.

Summary of sections:
TB-sequential section of tumor, bisected
T-tumor

6) The specimen is received fresh, labeled "Superior margin left breast" and consists of a piece of fibrofatty breast tissue measuring 4.3 x 3.2 cm, and

** Continued on next page **

[page 5 of 8]
----- Page 5 of 7
0.9 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

7) The specimen is received fresh, labeled "Medial margin left breast" and consists of a piece of fibrofatty breast tissue measuring 3.8 x 3.2, and 1.0 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

8) The specimen is received fresh, labeled "Inferior margin left breast" and consists of a piece of fibrofatty breast tissue measuring 4.0 x 3.9, and 1.5 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

9) The specimen is received fresh, labeled "Lateral margin left breast" and consists of a piece of fibrofatty breast tissue measuring 4.9 x 3.5cm and 1.2 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

10) The specimen is received fresh, labeled "Posterior margin left breast" and consists of a piece of fibrofatty breast tissue measuring 4.7 x 2.5 cm and 0.5 cm thick. A stitch marks the new margin of excision, which is inked black. No tumor is grossly identified. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

** Continued on next page **

[page 6 of 8]
Summary of Sections:

Part 1: SP: Sentinel node #1 level one left axilla

Block	Sect.	Site	PCs
1		bln	1

Part 2: SP: Sentinel node #2 level one left axilla

Block	Sect.	Site	PCs
1		bln	1

Part 3: SP: Non-sentinel tissue left axilla

Block	Sect.	Site	PCs
1		u	1

Part 4: SP: Sentinel node #3 level one left axilla

Block	Sect.	Site	PCs
1		u	1

Part 5: SP: Breast, left, 4:00, excision of tumor site

Block	Sect.	Site	PCs
1		T	1
2		TA	2
2		TB	2
2		TC	2

Part 6: SP: Breast, left, superior margin

Block	Sect.	Site	PCs
6		ss	6

Part 7: SP: Breast, left, medial margin

Block	Sect.	Site	PCs
5		ss	5

Part 8: SP: Breast, left, inferior margin

Block	Sect.	Site	PCs
6		ss	6

Part 9: SP: Breast, left, lateral margin

Block	Sect.	Site	PCs
5		ss	5

Part 10: SP: Breast, left, posterior margin

Block	Sect.	Site	PCs
5		ss	5

** Continued on next page **

[page 7 of 8]
Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

By:

Date Reported:

Addendum Diagnosis

PART #5: LEFT BREAST

ONCOTYPE TESTING RESULTS RECEIVED ON RECURRENCE SCORE =23.
AVERAGE RATE OF DISTANT RECURRENCE OF 15% (95% CI: 12%-18%).

TESTING WAS PERFORMED AT:

ONCOTYPE REPORT CAN BE FOUND IN

** End of Report **

[page 8 of 8]
Specimens Submitted:
1: LEFT BREAST 4:00

Test Performed:
FISH for detection of gene amplification

Methodology:
Fluorescence in situ Hybridization (FISH) is performed using FDA-approved
ERBB2 (HER2/NEU) PathVysion assay probes and procedure

DIAGNOSTIC INTERPRETATION:
HER2/ CEP 17 1.0 / NOT AMPLIFIED

Her-2/neu gene amplification is NOT detected.
(cut off ratio: > 2.2 HER2 gene amplified; < 1.8 HER2 gene not amplified;
1.8 2.2 equivocal)

LAB NOTES:

Block # 5 (TAL)
Specimen fixative type: Formalin
Adequate number of invasive tumor cells present: Yes
Number of invasive tumor cells counted: 20 + 20
Average number of HER2 probe signals per nucleus: 3.2
Average number of CEP17 chromosome probe signals per nucleus: 3.2
Average HER2/CEP 17 ratio: 1.0

The PathVysion HER2 DNA probe kit (Vysis) is an FDA-approved method
for assessment of HER2 gene amplification in breast cancer specimens. The
HER2 test results are reported in accordance with the ASCO/CAP guideline
recommendations for HER2 testing in breast cancer (J Clin Oncol 2007; 25
(1):118-145).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

Source: NCI Genomic Data Commons file 8adcbf51-dde0-47f2-ab5c-34582e14526e (TCGA-AO-A1KS.0FB93D92-81F6-4241-9094-4AABF70E6A0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).